Somatic mutation profile of tumor specimen MP2PRT-PATGNR-TMP1-A (aliquot MP2PRT-PATGNR-TMP1-A-1-0-D-A81Y-36) from MP2PRT case MP2PRT-PATGNR, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.4 years (1,975 days).
Specimen MP2PRT-PATGNR-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dd62648d-352e-4b55-9abe-ce6526145337.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATGNR-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATGNR-NB1-A-1-0-D-A81Y-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b6449c7e-d1e1-418a-8ba6-e4e9da47c64b

The open-access MAF lists 21 somatic variants for this specimen: 19 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 17, Silent 2, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.182A>T p.D61V | Missense Mutation (SNP) | VAF 113/438 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs121918461, CM013415, CM098208, COSV61004983, COSV61005256, COSV61011211; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABL1 | c.1543G>A p.V515I | Missense Mutation (SNP) | VAF 40/274 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as rs766145624, COSV59325968; called by muse, mutect2, varscan2
- CSPG4 | c.5983C>T p.R1995W | Missense Mutation (SNP) | VAF 152/378 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as rs529993656, COSV57902610; called by muse, mutect2, varscan2
- DOT1L | c.965T>C p.L322P | Missense Mutation (SNP) | VAF 109/213 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67107798; called by muse, mutect2, varscan2
- GDF2 | c.716C>T p.T239M | Missense Mutation (SNP) | VAF 99/464 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.347); catalogued as rs782560993; called by muse, mutect2, varscan2
- GSPT2 | c.1183G>A p.G395R | Missense Mutation (SNP) | VAF 236/721 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61214657; called by muse, mutect2, varscan2
- HECTD1 | c.6761A>T p.K2254I | Missense Mutation (SNP) | VAF 66/277 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV104434326; called by muse, mutect2, varscan2
- HSPB2 | c.155G>A p.R52Q | Missense Mutation (SNP) | VAF 131/522 reads (25%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.866); catalogued as rs1465051226, COSV57052049; called by muse, mutect2, varscan2
- MROH2A | c.3262G>A p.E1088K | Missense Mutation (SNP) | VAF 110/372 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.324); catalogued as rs758357204; called by muse, mutect2, varscan2
- MXRA5 | c.130C>T p.R44* | Nonsense Mutation (SNP) | VAF 203/852 reads (24%) | catalogued as COSV99478325; called by muse, mutect2, varscan2
- NXPH2 | c.263C>T p.T88M | Missense Mutation (SNP) | VAF 94/421 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV55645249; called by muse, mutect2, varscan2
- PTPRM | c.1664C>T p.P555L | Missense Mutation (SNP) | VAF 91/376 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1396219663, COSV59879109; called by muse, varscan2
- SEC16A | c.4058C>T p.S1353L | Missense Mutation (SNP) | VAF 120/384 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs374231100; called by muse, mutect2, varscan2
- TLR3 | c.2048A>G p.Y683C | Missense Mutation (SNP) | VAF 130/432 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs1205356006; called by muse, mutect2, varscan2
- TMEM108 | c.455G>A p.R152H | Missense Mutation (SNP) | VAF 116/446 reads (26%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.001); catalogued as rs139900505; called by muse, mutect2, varscan2
- VSIG1 | c.91G>A p.V31M | Missense Mutation (SNP) | VAF 93/654 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.626); catalogued as rs376781458; called by muse, varscan2
- ABCC1 | c.52T>C p.W18R | Missense Mutation (SNP) | VAF 92/346 reads (27%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- CNOT11 | c.877A>T p.I293F | Missense Mutation (SNP) | VAF 82/298 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- IGHD2-2 | c.29_30delinsA p.C10Yfs*? | Frame Shift Del (DEL) | VAF 79/253 reads (31%) | called by pindel, varscan2*
- EOLA2 | c.303C>G p.P101= | Silent (SNP) | VAF 175/817 reads (21%) | catalogued as rs368857106, COSV100778083; called by muse, mutect2, varscan2
- RELN | c.696C>T p.G232= | Silent (SNP) | VAF 90/208 reads (43%) | catalogued as COSV59016682; called by muse, varscan2
